Somatic mutation profile of tumor specimen BA3251D (aliquot aq-BA3251D) from BEATAML1.0 case 2815, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.6 years (27,621 days).
Specimen BA3251D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b872f0cf-60c1-455f-a60d-b913e27558b2.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3239D (Solid Tissue Normal), aliquot aq-BA3239D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/748f783a-c3b4-485c-8477-ad5ebc2789ac

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SORCS1 | c.562A>T p.I188F | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LARGE1 | c.2010C>T p.Y670= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as rs374331968; called by muse, mutect2, varscan2
